ALCHEMIST case ALCH-B2T7 — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/4028b682-d673-44eb-9c3c-90f73907be45

Demographics
Sex at birth: female.

Diagnoses (1)
1. Large cell carcinoma, NOS: Age at diagnosis: 62.1 years (22,700 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B2T7-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B2T7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B2T7-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 28; Percent tumor nuclei: 33; Percent normal cells: 48; Percent necrosis: 5; Percent stromal cells: 19; Percent lymphocyte infiltration: 74; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 2.
